CPTAC case C3L-00510 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e57d0f0-c8f5-4aec-acd4-5c00a0b67c66

Demographics
Sex at birth: female; Year of birth: 1936; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 80.3 years (29,337 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G1; Residual disease: R2; Days to last known disease status: 38 days; Progression or recurrence: no; Days to last follow up: 38 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.8 cm (a second GDC size field records 2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Uninvolved.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 38.

Other clinical attributes
- Weight: 85.46 kg; Height: 165.1 cm; BMI: 31.35; Comorbidities: Osteoarthritis.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Cigarettes per day: 4; Tobacco smoking quit year: 2006; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00510-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 170 mg.
- Sample C3L-00510-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 120 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00510-22: Section location: Right Lower Lobe; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-00510-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 160 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00510-23: Section location: Right Lower Lobe; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-00510-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 190 mg; Time between clamping and freezing: 29 minutes; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00510-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 90 mg.
- Sample C3L-00510-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 120 mg.
- Sample C3L-00510-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
- Sample C3L-00510-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: OCT; Freezing method: -20 (unit not recorded by GDC).
